CCDI case PBCGSP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/0be19d6d-7b3d-49dd-b6d1-a7223310a584

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 1.3 years (457 days).

Biospecimens (3 samples)
- Sample 0DRRTS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DRRU0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRRUI: Tissue type: Tumor; Specimen type: Solid Tissue.
